Somatic mutation profile of tumor specimen C3N-00755-71 (aliquot CPT0129520007) from CPTAC case C3N-00755, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; Tumor grade: G1.
Specimen C3N-00755-71: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fecf321b-a65d-4e05-89c9-5724a488ad72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00755-31 (Blood Derived Normal), aliquot CPT0130860002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66c01256-3911-4355-a7cc-dc02c7df7a2d

The open-access MAF lists 43 somatic variants for this specimen: 34 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 7, Splice Region 2, Frame Shift Ins 1, Frame Shift Del 1, Intron 1, In Frame Del 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 72/324 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- MYCN | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 88/430 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057519919, COSV55257406, COSV55259752; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 18/74 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.403A>G p.I135V | Missense Mutation (SNP) | VAF 94/441 reads (21%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.987); catalogued as rs587782360, CM991082, COSV64288466; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ATP6V0C | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV53550087; called by muse, mutect2
- CDKN1B | c.299A>G p.K100R | Missense Mutation (SNP) | VAF 68/316 reads (22%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs774291520; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD6 | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 15/148 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766515899, COSV58555051; called by muse, mutect2
- CIAO3 | c.1258G>A p.V420M | Missense Mutation (SNP) | VAF 83/437 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as rs574344672; called by muse, mutect2, varscan2
- ELFN2 | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.107); catalogued as rs1342040776, COSV101297448, COSV68744039; called by muse, mutect2, varscan2
- FBXW9 | c.1033G>A p.E345K (on ENST00000587955; = p.E325K on NM_032301.3) | Missense Mutation (SNP) | VAF 19/732 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.281); catalogued as rs999213921, COSV66710038; called by muse, mutect2
- HYOU1 | c.1309G>A p.V437I | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT tolerated (0.32); PolyPhen benign (0.06); catalogued as rs150229065; called by muse, mutect2
- KCND1 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 32/352 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs181033799, COSV99501772; called by muse, mutect2
- PCDHB15 | c.1399G>A p.A467T | Missense Mutation (SNP) | VAF 120/606 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV99178820; called by muse, mutect2, varscan2
- PEX1 | c.899C>T p.A300V | Missense Mutation (SNP) | VAF 20/387 reads (5%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs769114978, COSV50397929; called by muse, mutect2
- PRPF8 | c.5494C>T p.R1832C | Missense Mutation (SNP) | VAF 18/750 reads (2%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59262553; called by muse, mutect2
- RXFP3 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.474); catalogued as rs1442701882, COSV57505093; called by muse, mutect2
- SLC43A2 | c.1217+4C>T | Splice Region (SNP) | VAF 22/449 reads (5%) | catalogued as rs368456228; called by muse, mutect2
- SORT1 | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.971); catalogued as rs759824912; called by muse, mutect2, varscan2
- SPTA1 | c.6772C>A p.Q2258K | Missense Mutation (SNP) | VAF 47/243 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs368355710; called by muse, mutect2, varscan2
- TOX2 | c.1073C>T p.T358M (on ENST00000358131 / NM_001098798.2; = p.T334M on NM_032883.3) | Missense Mutation (SNP) | VAF 54/215 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs139449576, COSV57891803; called by muse, mutect2, varscan2
- UBC | c.443G>C p.R148P | Missense Mutation (SNP) | VAF 122/689 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as COSV100299085, COSV60059522; called by muse, mutect2, varscan2
- WNK3 | c.3842G>A p.R1281Q | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.098); catalogued as rs782475066, COSV100670830, COSV100672433; called by muse, varscan2
- XPO5 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 44/216 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.449); catalogued as rs746237786, COSV54830581; called by muse, mutect2, varscan2
- EDARADD | c.583C>A p.L195M (on ENST00000334232 / NM_145861.4; = p.L185M on NM_080738.4) | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FEN1 | c.178_185del p.T60Pfs*24 | Frame Shift Del (DEL) | VAF 23/207 reads (11%) | called by mutect2, pindel, varscan2
- LMNTD2 | c.399+3G>A | Splice Region (SNP) | VAF 35/205 reads (17%) | called by muse, mutect2, varscan2
- MOSPD2 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 18/185 reads (10%) | called by muse, mutect2
- PHTF1 | c.680G>T p.S227I | Missense Mutation (SNP) | VAF 62/345 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PTPRC | c.2920A>G p.N974D | Missense Mutation (SNP) | VAF 30/174 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.304); called by muse, varscan2
- RANBP2 | c.8893A>G p.M2965V | Missense Mutation (SNP) | VAF 34/406 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- SERAC1 | c.552C>G p.S184R | Missense Mutation (SNP) | VAF 13/183 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2
- TELO2 | c.151_153del p.K51del | In Frame Del (DEL) | VAF 62/511 reads (12%) | called by mutect2, pindel, varscan2
- TFE3 | c.698C>T p.A233V | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- TXNIP | c.830dup p.I278Dfs*4 | Frame Shift Ins (INS) | VAF 41/202 reads (20%) | called by mutect2, pindel, varscan2
- BAHCC1 | c.5259G>A p.K1753= | Silent (SNP) | VAF 13/378 reads (3%) | called by muse, mutect2
- CHST7 | c.1083C>T p.G361= | Silent (SNP) | VAF 20/426 reads (5%) | catalogued as rs956164037; called by muse, mutect2
- LTN1 | c.1137G>A p.L379= | Silent (SNP) | VAF 73/333 reads (22%) | called by muse, mutect2, varscan2
- MAGIX | c.390C>T p.R130= | Silent (SNP) | VAF 42/316 reads (13%) | catalogued as rs782308591, COSV100891932; called by muse, mutect2, varscan2
- MRTFB | c.2328C>T p.G776= (on ENST00000571589 / NM_001365412.2; = p.G726= on NM_014048.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 72/343 reads (21%) | called by muse, mutect2, varscan2
- NLRP1 | c.1710C>T p.D570= | Silent (SNP) | VAF 59/268 reads (22%) | called by muse, mutect2, varscan2
- SPTBN2 | c.5733C>T p.R1911= | Silent (SNP) | VAF 104/548 reads (19%) | catalogued as rs370302342; called by muse, mutect2, varscan2
- DKKL1 | c.-93G>A | 5'UTR (SNP) | VAF 10/336 reads (3%) | called by muse, mutect2
- PKM | c.-14+153G>A | Intron (SNP) | VAF 54/220 reads (25%) | called by muse, mutect2, varscan2
